Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A9ZG, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A9ZG-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

FINAL PATHOLOGIC DIAGNOSIS

ICD O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
JW 1/23/14

- A. Right pelvic lymph nodes, dissection: No tumor (0/3).
- B. Left pelvic lymph nodes, dissection: No tumor (0/2).
- C. Prostate, radical prostatectomy: Prostate adenocarcinoma, Gleason grade 5+4, score=9 , bilateral involvement, margins negative; see comment.

COMMENT:

Synoptic Comment for Prostate Tumors

- **Type of tumor:** Small acinar adenocarcinoma.
- **Location of tumor:** Left posterior midgland, slide C14; left anterior midgland, slide C15-C16; right posterior base, slide C4; right posterior mid glands, slides C10-C11; right posterior base, slide C20; right anterior apex, slide C4; right anterior midgland, slides C6-C8; right anterior base, slide C20.
- **Estimated volume of tumor:** 2.8 cm³.
- **Gleason score:** 5+4=9. A tertiary component of pattern 3 is also present. Drs and agree with the grading.
- **Estimated volume > Gleason pattern 3:** 70%.
- **Involvement of capsule:** None.
- **Extraprostatic extension:** None.
- **Margin status for tumor:** Negative.
- **Margin status for benign prostate glands:** Benign glands present at inked excision margins; slide C1, right apex.
- **High-grade prostatic intraepithelial neoplasia (HGPIN):** Not present.
- **Tumor involvement of seminal vesicle:** None.
- **Perineural infiltration:** Present.
- **Lymph node status:** Negative; total number of nodes examined: Five.
- **AJCC/UICC stage:** pT2cN0.
-

[page 2 of 3]
Specimen(s) Received

A: Right pelvic lymph nodes
B: Left pelvic lymph nodes
C: Prostate & seminal vesicles (fresh)

Clinical History

The patient is a 65-year-old man with prostate cancer, grade 4-5.

Gross Description

The specimen is received in three parts, each labeled with the patient's name and unit number. Parts A and B are received in formalin, and part C is received fresh.

Part A is additionally labeled "right pelvic LN," and consists of multiple soft, yellow-brown, fatty tissues (3.5 x 3.5 x 1.5 cm in aggregate). The specimen is extensively searched for lymph nodes. Three candidate lymph nodes are found and submitted in cassette A1.

Part B is additionally labeled "left pelvic LN," and consists of one soft, tan-yellow, fatty tissue (4 x 1 x 1 cm). The specimen is extensively searched for lymph nodes. Multiple candidate lymph nodes are found and submitted as follows:

B1: Four intact nodes.
B2: One large, intact node.

Part C is additionally labeled "prostate and seminal vesicles," and consists of a radical prostatectomy specimen (52 gm; 4 cm from apex to base x 4.7 cm from lateral to medial x 4 cm from anterior to posterior).

GROSS PATHOLOGIC FINDINGS: There are two suspicious areas. The first suspicious area is tan-yellow (1.2 x 1 x 1 cm), located abutting into the margin inked black (less than 0.1 cm), also located in serial slices 5, 6 and 7. The second suspicious area is tan-white (1.2 x 1 x 0.6 cm), located within 0.4 cm from the right anterior inked green margin, and also located in serial slices 2 and 3. The remaining prostate parenchyma is tan-light brown. The seminal vesicle/vas deferens bundles (right 2.5 x 1.5 x 0.5 cm; left 2 x 1.5 x 0.5 cm) are soft, lobulated, red-tan, without obvious lesions or mass. Some of the prostate is taken by the (serial slice 6 and anterior half of slice 7).

ORIENTED BY: Anatomic landmarks.

INKING:

- Green: Right anterior.
- Blue: Left anterior.
- Black: Posterior.

GROSS PHOTOGRAPHS: Yes.

TOTAL NUMBER OF SLICES: 7.

AVERAGE SLICE THICKNESS: 0.4 cm.

CASSETTES: Representative sections are submitted as follows:

Apical margins, entirely submitted in perpendicular sections

C1: Right apex.
C2: Left apex.
C3: Serial slice 1.
C4: Right half of serial slice 2.
C5: Left half of serial slice 2.

Right anterior quadrant

C6: Slice 3.
C7: Slice 4.
C8: Slice 5.

Right posterior quadrant

C9: Slice 3.

[page 3 of 3]
C10: Slice 4.
C11: Slice 5.
Left posterior quadrant
C12: Slice 3.
C13: Slice 4.
C14: Slice 5.
Left anterior quadrant
C15: Slice 3.
C16: Slice 4.
C17: Slice 5.
Bladder margins, entirely submitted in perpendicular sections
C18: Right.
C19: Left.
Prostatic/seminal vesicle junction and cross-section of vas deferens
C20: Right.
C21: Left.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Electronically signed out on

Source: NCI Genomic Data Commons file 770009f9-2894-42fa-b652-e6448ee256e7 (TCGA-V1-A9ZG.D7B1ABAE-1A72-496C-B11F-469F65B37347.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).